Gene-level copy-number profile of tumor specimen TARGET-10-PATXSK-09A from TARGET case TARGET-10-PATXSK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,279 days).
Specimen TARGET-10-PATXSK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.edc1d20e-7d8c-517a-8f91-4ae88aa157e5.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATXSK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 368 have no estimate.
https://portal.gdc.cancer.gov/files/b9826218-7ee5-4cbc-8fb2-6d0eede7f7e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 114; copy number 1: 2,504; copy number 2: 53,756; copy number 3: 3,767; copy number 4: 72; copy number 5: 42.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,335,514, 14 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:142,618,849–142,793,368, 28 genes: TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:20,341,669–22,128,103, 62 genes (within-gene range 0–1) (broad region; genes not listed).
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr17:18,450,244–18,551,705, 9 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 42 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 5 (within-gene range 2–5): AC244205.1.
- chr2:88,857,161–89,268,506, 41 genes, copy number 5: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33.

Autosomal genes at a single copy (total copy number 1): 116. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
